Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEA-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy and cholecystectomy

Organs: Liver (11.5 x 11.3 x 4.0 cm, 226.5 g), gallbladder (10.0 cm in length, 3.5 cm in diameter, and 0.5 cm in thickness)

Lesion: A well-defined mass (4.0 x 3.0 x 3.8 cm)

Cut surface: Pale pink to tan, multinodular solid and slightly firm mass without necrosis

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (Safety margin 0.5 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Unremarkable

Gross photo: Present

Blocks

T1-4, mass x 4

L, liver parenchyma x 1

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular, Pseudoglandular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Complete capsule

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No, safety margin (0.5 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

Others: Periportal fibrosis (stage 2)

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

W 012014

[page 2 of 2]
NOT reported. Gross:

NOT reported. Gross:

Esophagus, scopic, squamous cell carcinoma

esophagus,ectomy,squamous cell carcinoma
lymph node,ectomy,frozen biopsy,no tumor

Stomach, body, scopic, chronic gastritis, erosive

Esophagus, anastomosis site, scopic, chronic inflammation

Esophagus, scopic, no tumor

liver,ectomy,hepatocellular carcinoma
T56000, P10, M81703
gallbladder,ectomy,chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated

Gallbladder, cholecystectomy :

Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file fc73a33a-0053-42ae-8731-4ec174e757f0 (TCGA-DD-AAEA.E793074A-8F17-4698-9D99-BA2053E8E3C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).